Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AC0F, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AC0F-TTP1-A (Primary Tumor).

[page 1 of 12]
Results History

IMMUNO...STOCHEMISTRY (Order [REDACTED])

Result Date - [REDACTED] ++12

Component Results

Component

Report, pathology

Provider: [REDACTED]

Collected: [REDACTED] +0 Case #: [REDACTED]

Immunohistochemistry Report

FINAL PATHOLOGIC DIAGNOSIS

IMMUNOHISTOCHEMISTRY (LEFT BREAST, [REDACTED] B1)

Estrogen Receptor -negative, positive on-slide control

Progesterone Receptor -negative, positive on-slide control

Her2neu -positive, 90%, 3+/strong

** Report Electronically Signed by [REDACTED] **

Studies

[DISCLAIMER: This immunoperoxidase panel was developed and its performance characteristics determined by the [REDACTED]]

[REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Monoclonal antibodies (clones SP1, and PgR636) are used as part of an LSAB immunohistochemical assay to detect estrogen and progesterone receptors, respectively, on formalin-fixed paraffin-embedded tissue. The percentage of stained tumor nuclei is determined manually. Specimens with less than 5% of tumor nuclei stained are considered negative. Specimens with 5% or greater of tumor nuclei stained are considered positive.

The PATHWAY9 HER2 (clone 4B5) test is used to assess HER2 protein overexpression in formalin-fixed paraffin-embedded tissue. Staining interpretation and scoring of the PATHWAY9 test are performed in accordance with the Ventana PATHWAY9 package insert, where a HER2 expression score is assigned (0-3+). HER2 overexpression (3+) is defined as strong, complete membrane staining in more than 30% of tumor cells. An equivocal result (2+) is defined as weak to moderate complete membrane staining in more than 10% of tumor cells. A negative result (0-1+) is defined as a faint/barely perceptible incomplete membrane staining in more than 10% of tumor cells (1+), or no staining or membrane staining in less than 10% of tumor cells (0). This assay is FDA-cleared for in vitro diagnostic use as an aid in identifying patients for whom Herceptin9 (trastuzumab) treatment is being considered. Unless otherwise specified, the infiltrating component is evaluated.]

Clinical History

A [REDACTED] female with history of right breast carcinoma. Now has a left breast metastatic carcinoma in dermal lymphatics.

Specimen(s) Received

A: I-2 CONSULT - ER/PR/HER2NEU - SKIN - LT BREAST [REDACTED]

B1) 1BK

[page 2 of 12]
[REDACTED]

Patient Name: [REDACTED]

Med. Rec #: [REDACTED]

DOB/Age: [REDACTED]

Sex: F [REDACTED]

Facility: [REDACTED]

Location: [REDACTED]

[REDACTED]

Result Date - [REDACTED]

+8

[REDACTED]

[page 3 of 12]
Results History

SURGICAL PATHOLOGY (Order [REDACTED])

Result Date - [REDACTED] +5

Component Results

Component Report, pathology

Provider: [REDACTED]

Collected: [REDACTED] +0 Case #: [REDACTED]

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. SKIN, LEFT FOREHEAD, EXCISION:
- NEUROFIBROMA.

B. SKIN, LEFT BREAST, PUNCH BIOPSY:
- METASTATIC CARCINOMA IN DERMAL LYMPHATIC SPACES CONSISTENT
WITH METASTATIC BREAST
CARCINOMA (SEE COMMENT).

Comment

Representative slide from patient's previous case [REDACTED]
is reviewed and the carcinoma shows similar histologic features to
that seen in this case. Findings were reported to [REDACTED]
by phone voicemail on [REDACTED] +2

Clinical History

1. NF. 2. Rule out inflammatory breast CA (red, almost nevoid
largely blanchable patches on left breast).

Gross Description

A. Received in formalin and labeled [REDACTED] and "#1" is a
tan ellipse of skin 1.3 x 1.1, and excised to a depth of 0.4 cm.
The ellipse is marked with blue ink, serially sectioned. (A1).
Tips. (A2). Remainder. Also in the container are two tan tissue
fragments, 1.1 and 0.7 cm in greatest dimension. Each is bisected
and entirely submitted in (A3).

B. Received in formalin and labeled [REDACTED] and "#2" is a
tan punch biopsy of skin 0.6 cm in diameter and 1.2 cm in depth.
Bisected and entirely submitted in (B1).

[REDACTED] +1

Specimen(s) Received

A: SKIN EXCISION, NOT ORIENTED - LEFT FOREHEAD
B: SKIN PUNCH BX - LEFT BREAST

Patient Name: [REDACTED]

Med. Rec #: [REDACTED]

DOB/Age: [REDACTED]

Sex: F

Facility: [REDACTED]

Location: [REDACTED]

[page 4 of 12]
Result Date - [REDACTED] +1

[page 5 of 12]
Transcription Result

Type	ID	Date and Time	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]
	+13		

Procedure Orders:

1. CT THORAX, W CONTRAST
2. CT ABDOMEN, W CONTRAST
3. CT PELVIS, W CONTRAST

+13

Document Text

CT CHEST, ABDOMEN, & PELVIS W/ CONTRAST

+13

** HISTORY **:

[REDACTED] female with neurofibromatosis and a right mastectomy in [REDACTED] Now with cancer in skin of the left breast. CT for restaging. -1183

** FINDINGS **:

Technique: 5 mm axial images obtained from lung apices to symphysis pubis after uncomplicated administration of intravenous and oral contrast.

Comparison: No direct comparisons available. Compared with report from [REDACTED] CT. -1171

Several cutaneous nodular densities along the skin are in keeping with patient's history of neurofibromatosis.

CHEST: Patient is status post right mastectomy and axillary dissection. There is mild soft tissue thickening along the left breast nonspecific in appearance.

There is left axillary adenopathy with largest node measuring 19 x 22 mm axially. No pathologic adenopathy is identified within the mediastinum, hila or right axilla. 7 mm prevascular space lymph node is not enlarged.

There are multiple bilateral pulmonary nodules (at least 20) compatible with pulmonary metastases. Largest nodule in the right measures 8 mm in the right lower lobe. Largest nodule on the left measures 9 mm in the left lower lobe.

There is no pleural or pericardial effusions.

ABDOMEN/PELVIS: No evidence for bowel obstruction, pathologic adenopathy, ascites or abdominal aortic aneurysm.

There are several well marginated hypodensities within the liver most likely representing incidental liver cysts. Some of these appear bilobed with the largest measuring 3.3 x 2.3 cm. Similar findings have been described previously. There is diffuse low attenuation of the liver suggesting fatty infiltration.

Spleen, pancreas, gallbladder, biliary ducts, adrenal glands, kidneys, uterus and adnexal structures are unremarkable. There is a nondistended bladder and some colonic diverticula.

BONES: There are scattered osseous degenerative changes and no suspicious appearing osseous lesion is identified. Small round sclerotic foci in the knee right scapula is likely an incidental bone island.

[page 6 of 12]
** IMPRESSION **:

1. Left axillary adenopathy and numerous pulmonary nodules compatible with pulmonary metastasis. There is mild thickening of the left breast skin.
2. Status post right mastectomy and axillary nodal dissection.
3. No evidence for metastatic disease to the abdomen and pelvis. No suspicious appearing osseous lesions.
4. Several incidental hepatic cysts.

+13

Results phoned to [REDACTED] voicemail at [REDACTED].
Action required dictation.

[page 7 of 12]
Transcription Result

Type	ID	Date and Time	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]

Procedure Orders:

1. CT THORAX, W CONTRAST [REDACTED] ordered by [REDACTED]

+669

Document Text

CT CHEST, ABDOMEN, AND PELVIS WITH CONTRAST

+669

** HISTORY **:

[REDACTED] female with metastatic breast cancer on chemotherapy, with prior CT from [REDACTED] showing lung nodules, please assess.

+13

** FINDINGS **:

Comparison: [REDACTED] and [REDACTED]

+271

+13

Technique: Transaxial CT imaging of the chest, abdomen, and pelvis was following uneventful administration of oral contrast and non-ionic, iodinated intravenous contrast (Omnipaque-350, 100 mL).

Right chest wall access port remains in place, tip in the right atrium.

Thorax: No new pulmonary nodules. Minimal subpleural increase in parenchymal density is felt to be secondary to given the posterior and dependent location. No change in right upper lobe subcentimeter cyst on image 20.

No pleural effusion or thickening. No pneumothorax. No hilar or mediastinal lymphadenopathy. Previously described periaortic lymph node interposed between the azygous vein and a thoracic aorta is no longer seen. Principal thoracic vascular structures remain patent and intact, revealing mild noncalcified and calcified atherosclerotic changes. The heart is normal in size, without pericardial effusion.

No suspicious osseous lesions in the thorax. Minor degenerative changes of the thoracic spine are evident.

Patient is status post right mastectomy and right axillary dissection. No left axillary lymph nodes are seen. Scattered stranding is seen in that region. Mild skin thickening is noted over the left breast region.

Numerous cutaneous nodules are seen, compatible with history of neurofibromatosis.

Abdomen/pelvis: The liver is normal in size and configuration, without focal suspicious hepatic lesion. Again noted are the multiple hepatic cysts. They are unchanged.

The spleen, pancreas, adrenal glands, and kidneys are stable and unremarkable.

The small bowel and colon are normal in caliber and distribution, without evidence for obstruction or surrounding inflammatory changes. A normal appendix is present. Minimal sigmoid diverticula, without CT features of diverticulitis.

No lymphadenopathy in the abdomen or pelvis. Visible abdominal

[page 8 of 12]
and pelvic vascular structures revealed minimal non-calcified atherosclerotic changes, but are otherwise unremarkable.

The uterus and adnexa are unremarkable.

No suspicious osseous lesions; degenerative changes of the lumbosacral region are again noted in the context of patient's previously described lumbar levoscoliosis.

**** IMPRESSION **:**

No evidence for recurrent malignancy in the chest, abdomen, or pelvis at contrast enhanced CT. Since [REDACTED] stable examination.

+271

[page 9 of 12]
Transcription Result

Type	ID	Date	Author
Procedures	[REDACTED]	[REDACTED] +2723	[REDACTED]

Procedure Orders:

1. CT THORAX, W CONTRAST [REDACTED] ordered by at [REDACTED] +2723
2. CT ABDOMEN AND PELVIS, W CONTRAST [REDACTED] ordered by at [REDACTED] +2723

Document Text

CT CHEST, ABDOMEN, AND PELVIS

** HISTORY **:

Metastatic breast cancer treated with chemotherapy.

** FINDINGS **:

Comparison: [REDACTED] +2165

Technique: Axial images of the chest, abdomen, and pelvis were obtained with IV contrast administration.

CTDI: 11.84 mGy

DLP: 749.38 mGy-cm

Chest: No axillary, hilar, or mediastinal lymphadenopathy is seen. No pulmonary nodule or pleural effusion is seen. Right breast is surgically absent.

Abdomen pelvis: Multiple hepatic cysts are stable. No new hepatic lesion or biliary ductal dilatation is seen. The spleen, pancreas, gallbladder, adrenal glands, and kidneys are normal. No new mesenteric, retroperitoneal, or pelvic lymphadenopathy is seen. No free air, free fluid, or bowel dilatation is seen. Mild aortic atherosclerosis is seen.

A levoconvex lumbar scoliosis is seen with severe degenerative spondylosis. No new suspicious bone lesion is seen.

** IMPRESSION **:

No evidence of metastatic disease.

Mild aortic atherosclerosis.

DD:

DT:

[REDACTED]
+2723

[page 10 of 12]
BL imaging = Day 13

[page 11 of 12]
Level 1 case

BL = Day 13 (left image), RT lung met, 10 x 16 mm

BL + 22 months, Day 698 (center image), BL + 7.5 years, Day 2714 (right image)

Lung met no longer found on follow up imaging, CR for lesion

[page 12 of 12]
Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB/Age: [REDACTED]

Sex: F

Facility: [REDACTED]

Location: [REDACTED]

Patient Type: [REDACTED]

Physician(s): [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A. SKIN, LEFT FOREHEAD, EXCISION:
- NEUROFIBROMA.

B. SKIN, LEFT BREAST, PUNCH BIOPSY:
- METASTATIC CARCINOMA IN DERMAL LYMPHATIC SPACES CONSISTENT WITH METASTATIC BREAST CARCINOMA (SEE COMMENT).

*** Report Electronically Signed by [REDACTED]

Comment

Representative slide from patient's previous case features to that seen in this case. Findings were reported to

is reviewed and the carcinoma shows similar histologic by phone voicemail on

Clinical History

1. NF. 2. Rule out inflammatory breast CA (red, almost nevoid largely blanchable patches on left breast).

Gross Description

A. Received in formalin and labeled "[REDACTED]" and "#1" is a tan ellipse of skin 1.3 x 1.1, and excised to a depth of 0.4 cm. The ellipse is marked with blue ink, serially sectioned. (A1). Tips. (A2). Remainder. Also in the container are two tan tissue fragments, 1.1 and 0.7 cm in greatest dimension. Each is bisected and entirely submitted in (A3).

B. Received in formalin and labeled "[REDACTED]" and "#2" is a tan punch biopsy of skin 0.6 cm in diameter and 1.2 cm in depth. Bisected and entirely submitted in (B1).

Specimen(s) Received

A: SKIN EXCISION, NOT ORIENTED - LEFT FOREHEAD
B: SKIN PUNCH BX - LEFT BREAST

ICD-0-3

carcinoma, NOS 8010/3

Site: breast, skin C44.5

ICD-10

Other specified malignant neoplasm of skin of breast C44.591

hw
10/13/15

Source: NCI Genomic Data Commons file 9a972c57-42f1-4654-9047-4164570a344f (ER0197 ER-AC0F Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).